CCDI case PBCHDL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b5e892fd-c3cc-4782-99d8-f133c82b32eb

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.5 years (2,005 days).

Biospecimens (3 samples)
- Sample 0DU7ZL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU802: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU81C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
